Somatic mutation profile of tumor specimen 0DS6L9 from CCDI case PBCHTB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 15.5 years (5,664 days).
Specimen 0DS6L9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da822a9b-1d5f-4780-880a-b3e314592313.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS6LN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4aa7ce3-b83e-463d-95a6-b0a8a34920fb

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 2, Frame Shift Del 1, RNA 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 96/623 reads (15%) | catalogued as COSV100535302; called by muse, mutect2, varscan2
- ADGRL2 | c.2620G>T p.G874C (on ENST00000370717 / NM_001366005.1; = p.G861C on NM_012302.4) | Missense Mutation (SNP) | VAF 26/805 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KSR1 | c.584G>A p.G195E (on ENST00000644974 / NM_001367810.1; = p.G58E on NM_014238.2) | Missense Mutation (SNP) | VAF 37/672 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.444); called by muse, mutect2
- MICA | c.949_961del p.A317Ifs*65 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2*, pindel
- PHF3 | c.6066G>A p.R2022= | Silent (SNP) | VAF 38/636 reads (6%) | called by muse, mutect2
- POTEG | c.984C>T p.N328= | Silent (SNP) | VAF 20/231 reads (9%) | catalogued as rs372243218; called by muse, mutect2, varscan2
- CABP1 | c.*52G>A | 3'UTR (SNP) | VAF 15/287 reads (5%) | called by muse, mutect2
- LINC02688 | n.1869C>T | RNA (SNP) | VAF 12/167 reads (7%) | catalogued as rs1440061990; called by muse, mutect2
